TARGET case TARGET-40-NAAHBS — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of limbs. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c55de20b-7c24-58df-ae4d-1b61c3e714d4

Demographics
Sex at birth: male; Age at index: 10 years; Vital status: Dead; Days to death: 911 days (2.5 years).

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C40.2; Tissue or organ of origin: Long bones of lower limb and associated joints; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 10.4 years (3,815 days); Year of diagnosis: 2000; Metastasis at diagnosis: Metastasis, NOS; Days to last follow up: 911 days (2.5 years); Sites of involvement: Bone, NOS.
   Pathology details: Necrosis percent: 95.
   Treatment given: Protocol identifier: BCM.

Follow-up (2 entries)
- Days to follow up: 822 days (2.3 years); Days to first event: 822 days (2.3 years); First event: Relapse.
- Days to follow up: 911 days (2.5 years); Year of follow up: 2002.

Biospecimens (2 samples)
- Sample TARGET-40-NAAHBS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-40-NAAHBS-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Validation_20230329.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 911
- Protocol: BCM
- Disease at diagnosis: Metastatic
- Metastasis site: Bone
- Primary tumor site: Leg/foot
- Specific tumor site: Femur
- Specific tumor region: Distal
- Definitive Surgery: Limb sparing
- Primary site progression: Lung, spine
- Histologic response: Stage 3/4 (91-100 % necrosis)
